Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H3, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H3-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. LIVER, PORTION OF SEGMENT 2 AND 3, PARTIAL HEPATECTOMY:
Hepatocellular carcinoma, well-differentiated.
See Key Pathological Findings.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Ancillary Studies

Immunohistochemistry stain for CD31, performed with adequate controls on block A5, highlight the vascular invasion.
Special stains for reticulin and trichrome were performed with adequate controls on block A3 and A11 and were reviewed.
Special stains for Iron, PAS, and PAS-D were performed with adequate controls on block A11 and were reviewed.

Key Pathological Findings

Specimen:	Liver
Procedure:	Partial hepatectomy
Tumor size:	5.9 X 5.2 x 2.2 cm
Tumor focality:	Solitary
Histologic type:	Hepatocellular carcinoma
Histologic grade:	Well-differentiated (G1)
Tumor extension:	Tumor is within 1 mm of visceral peritoneum
Parenchymal margin:	Uninvolved by invasive carcinoma (tumor is at least 8 mm away from the parenchymal margin)
Vascular invasion (macroscopic):	Not identified
Vascular invasion (microscopic):	Present
Perineural invasion:	Not identified
Pathological stage:	pT2 pNX pMX
Additional pathologic finding:	Non-neoplastic liver show macrovesicular steatosis with zonal distribution (Zone 3) and no fibrosis (satge 0-1). There is no increase in stainable iron.

ICD-O.3
Carcinoma, hepatocellular
NOS 8170/3
Site: Liver C22.0
J 4/28/14

Specimen(s) Received

- A. PORTION OF SEG II AND III FS

Clinical History

[page 2 of 2]
LIVER CANCER

Frozen Section Diagnosis

FSA1: Malignant neoplasm, favor hepatocellular carcinoma.

Intradepartmental Consultation: The case was also reviewed by _____, who concurs with the above interpretation.

FSA2: Margins (perpendicular), no evidence of malignancy.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by _____ in _____ at _____.

I, _____ have performed the intraoperative consultations and issued the above diagnosis.

Gross Description

A. The specimen is received fresh for frozen section, labeled "portion of segment 2 and 3" and consists of 89 grams, 8.7 x 6.5 x 3.1 cm wedge of liver with a moderate amount of attached fat. The fat is focally adherent to the capsule and there is a 3.5 x 3.2 cm portion of adherent diaphragm. Sectioning reveals a lobulated, circumscribed, 5.9 x 5.2 x 2.2 cm tan nodule with focal necrosis and gray-white fibrous septi. The tumor extends into the adherent fat. The parenchymal margin is inked blue and the diaphragm margin black. The specimen is serially sectioned. Representative sections are submitted as labeled.

FSA1: Tumor

FSA2: Closest perpendicular parenchymal margin

A3: Tumor to overlying diaphragm

A4: Tumor to adjacent parenchyma

A5: Tumor

A6-A8: Tumor to adherent fat

A9-A10: Tumor

A11: Parenchymal margin

Tissue is submitted to Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file 7e34a94b-517e-4e04-9d24-082bb74c751c (TCGA-2Y-A9H3.83E9C775-EE1D-4763-A448-BB677FC01FA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).